Somatic mutation profile of tumor specimen TARGET-15-SJMPAL012418-09A.3 (aliquot TARGET-15-SJMPAL012418-09A.3-01D) from TARGET case TARGET-15-SJMPAL012418, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: male; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 16.3 years (5,940 days).
Specimen TARGET-15-SJMPAL012418-09A.3: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a062079f-50eb-4332-aa60-390396f0c96d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL012418-14A (Bone Marrow Normal), aliquot TARGET-15-SJMPAL012418-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aa1e21a9-942f-47ae-81e7-c885abf05ff0

The open-access MAF lists 23 somatic variants for this specimen: 16 protein-altering or splice-affecting, 2 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 2, Frame Shift Ins 2, Intron 2, 3'UTR 1, 5'UTR 1, Splice Site 1, Nonsense Mutation 1, 3'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CLK4 | c.380G>A p.R127H | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs147395654; called by muse, mutect2
- CTCFL | c.998G>T p.R333L | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs956619364, COSV99712548; called by muse, mutect2
- KIF2B | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs753464095, COSV52127156; called by muse, mutect2, varscan2
- MSL2 | c.934A>C p.S312R | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.525); catalogued as rs1428378462; called by muse, varscan2
- NME8 | c.1645C>G p.P549A | Missense Mutation (SNP) | VAF 49/91 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52257602, COSV99553734; called by muse, mutect2, varscan2
- NME8 | c.1646C>T p.P549L | Missense Mutation (SNP) | VAF 49/91 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52254074; called by muse, mutect2, varscan2
- NUP214 | c.4133dup p.V1379Gfs*60 | Frame Shift Ins (INS) | VAF 24/54 reads (44%) | catalogued as rs780417788; called by mutect2, varscan2
- WT1 | c.1303+5G>C | Splice Region (SNP) | VAF 56/100 reads (56%) | catalogued as CS115106; called by muse, varscan2
- AGTPBP1 | c.2909G>T p.R970L (on ENST00000357081 / NM_001330701.2; = p.R930L on NM_015239.2) | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- ASXL2 | c.2751_2752insCCTG p.S918Pfs*9 | Frame Shift Ins (INS) | VAF 23/58 reads (40%) | called by mutect2, pindel, varscan2
- AVPR2 | c.874C>A p.L292M | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); called by muse, mutect2
- CRTAP | c.459C>A p.F153L | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT tolerated (0.09); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- DCP1A | c.802G>T p.A268S | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.087); called by muse, mutect2
- GC | c.551C>A p.S184Y | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- RANBP6 | c.1219G>T p.E407* | Nonsense Mutation (SNP) | VAF 3/32 reads (9%) | called by muse, mutect2
- RXRB | c.1256+1G>T p.X419_splice | Splice Site (SNP) | VAF 3/43 reads (7%) | called by muse, mutect2
- NBAS | c.3846G>A p.Q1282= | Silent (SNP) | VAF 54/120 reads (45%) | called by muse, mutect2, varscan2
- POTEH | c.258C>T p.H86= | Silent (SNP) | VAF 75/318 reads (24%) | catalogued as rs370869918; called by muse, mutect2, varscan2
- AAK1 | c.*9779G>T | 3'UTR (SNP) | VAF 4/17 reads (24%) | called by muse, mutect2
- ACSL6 | c.-21G>T | 5'UTR (SNP) | VAF 3/29 reads (10%) | catalogued as COSV99732407; called by muse, mutect2
- APOL3 | c.223+6085G>T | Intron (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2
- SRL | c.62-2365G>T | Intron (SNP) | VAF 3/13 reads (23%) | catalogued as rs1224114373; called by muse, mutect2
- TNNT3 | chr11:1938690 C>A | 3'Flank (SNP) | VAF 4/32 reads (13%) | catalogued as rs1376129166; called by muse, mutect2
